Somatic mutation profile of cancer-model specimen HCM-WCMC-0671-C18-85A (3D Organoid, passage 9; aliquot HCM-WCMC-0671-C18-85A-01D-A85C-36), derived from the primary tumor of HCMI case HCM-WCMC-0671-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 47.4 years (17,322 days).
Specimen HCM-WCMC-0671-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acd919b7-fbb8-4e23-9177-48b30e05d8b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0671-C18-10A (Blood Derived Normal), aliquot HCM-WCMC-0671-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bbad1fe-a214-4000-acfc-36dcab857d08

The open-access MAF lists 111 somatic variants for this specimen: 73 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 35, Nonsense Mutation 3, 3'UTR 1, 5'Flank 1, RNA 1, Frame Shift Del 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 348/522 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.5401G>A p.E1801K | Missense Mutation (SNP) | VAF 517/914 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs397516248, CM1410901, COSV100806734; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 288/288 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- YY1AP1 | c.2125G>T p.E709* (on ENST00000295566 / NM_139118.2; = p.E652* on NM_018253.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 378/502 reads (75%) | catalogued as rs1057519598, COSV55120465; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 198/306 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as COSV56295981; called by muse, varscan2
- AP002748.5 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370913745; called by muse, varscan2
- ARHGEF19 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.262); catalogued as COSV54615416, COSV54617495; called by muse, mutect2, varscan2
- BCHE | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 47/342 reads (14%) | catalogued as CM055098; called by muse, mutect2, varscan2
- CELSR3 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 144/522 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV99375237; called by muse, varscan2
- CFTR | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 189/406 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs397508365, CM972954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.3782C>T p.T1261M | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs772890229; called by muse, varscan2
- DKK2 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 204/318 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs1366887020, COSV99568057; called by muse, varscan2
- DMD | c.8852G>A p.R2951H | Missense Mutation (SNP) | VAF 160/324 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs72466567, COSV58933390; ClinVar: uncertain significance / benign; called by muse, varscan2
- ERCC2 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 182/526 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs759930858, COSV55540243; called by muse, varscan2
- FAM90A1 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 119/437 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1338068289, COSV56712500, COSV56714018; called by muse, mutect2, varscan2
- FKBP7 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 143/266 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs778701740; called by muse, mutect2, varscan2
- GALNT12 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 236/459 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV66663311; called by muse, mutect2, varscan2
- GDPD2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 184/748 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs777943165; called by muse, mutect2, varscan2
- HS3ST3A1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 165/594 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs750522076, COSV52372487; called by muse, varscan2
- IFT140 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 154/443 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771255082; called by muse, mutect2, varscan2
- IL31RA | c.2170C>A p.Q724K | Missense Mutation (SNP) | VAF 114/246 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100732478; called by mutect2, varscan2
- IRAG2 | c.3435G>T p.L1145F (on ENST00000636465; = p.L190F on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/781 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63140948; called by muse, mutect2
- ITGA8 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 208/611 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100958992; called by muse, varscan2
- KDM4D | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 170/462 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as rs781785317; called by muse, mutect2, varscan2
- KIAA1549L | c.5267C>T p.S1756L (on ENST00000321505; = p.S2053L on NM_012194.3) | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1205996425, COSV58584314; called by muse, mutect2, varscan2
- KLF5 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 426/594 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66614378, COSV66615313; called by muse, varscan2
- KLHL38 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 510/823 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373548260; called by muse, varscan2
- L1CAM | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 34/1096 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as CM099770; called by muse, mutect2
- LLGL1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs571000675; called by muse, mutect2
- MYO3A | c.4163G>T p.R1388I | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV56329554; called by muse, mutect2, varscan2
- NEUROD1 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 182/534 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765540175, COSV54548386; called by muse, varscan2
- NIPBL | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 161/304 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as rs150498581, COSV99241547; called by muse, varscan2
- NLRP6 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 364/545 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs777994754, COSV56459160, COSV56459330; called by muse, varscan2
- OR11H12 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 134/1549 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1397853665; called by muse, mutect2
- OR2W3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 206/528 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.806); catalogued as rs759398397, COSV64455968; called by muse, varscan2
- OR9I1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs145179217; called by muse, mutect2, varscan2
- PPP1R2C | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 129/277 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs779855030, COSV65363978; called by muse, varscan2
- PRELP | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 533/705 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554590706, COSV58116609; called by muse, mutect2, varscan2
- PTGER3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 209/442 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV100138502, COSV60695422; called by muse, varscan2
- RAB11FIP5 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 175/454 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs372149039, COSV50248399; called by muse, mutect2, varscan2
- RBM12 | c.1350T>A p.F450L | Missense Mutation (SNP) | VAF 336/502 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58290226; called by muse, varscan2
- RP1L1 | c.4529C>T p.A1510V | Missense Mutation (SNP) | VAF 164/345 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs373409421; called by muse, varscan2
- SETD3 | c.576_578del p.D192del | In Frame Del (DEL) | VAF 204/342 reads (60%) | catalogued as rs748875088; called by mutect2, pindel, varscan2
- SLC13A3 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 66/896 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324143927, COSV51716411; called by muse, mutect2
- SLC25A53 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 308/715 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782336534; called by muse, varscan2
- TUBA3C | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 414/587 reads (71%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs1333388009, COSV104433929; called by muse, varscan2
- UBQLN3 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 135/426 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1284294682, COSV100294044; called by muse, mutect2, varscan2
- UGT2B10 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55322200; called by muse, mutect2, varscan2
- ZBTB33 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 282/670 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.193); catalogued as COSV58532966; called by muse, varscan2
- ZFHX4 | c.9230C>T p.T3077M | Missense Mutation (SNP) | VAF 371/592 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs377249680; called by muse, mutect2, varscan2
- ZNF195 | c.914G>A p.C305Y (on ENST00000399602 / NM_001130520.3; = p.C233Y on NM_007152.5) | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs964710282; called by muse, varscan2
- ZNF791 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV58481025; called by muse, mutect2, varscan2
- APC | c.4188del p.F1396Lfs*19 | Frame Shift Del (DEL) | VAF 104/174 reads (60%) | called by pindel, varscan2
- ARSG | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 145/310 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ATP6V1FNB | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 184/639 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CAPS2 | c.345A>T p.K115N | Missense Mutation (SNP) | VAF 99/143 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD69 | c.558T>G p.C186W | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP170 | c.1661C>A p.A554E | Missense Mutation (SNP) | VAF 71/408 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by mutect2, varscan2
- FBF1 | c.1165C>A p.L389M (on ENST00000586717; = p.L403M on NM_001319193.1) | Missense Mutation (SNP) | VAF 146/306 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); called by muse, varscan2
- FBN2 | c.3677C>T p.S1226F | Missense Mutation (SNP) | VAF 151/274 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FNIP1 | c.1200C>T p.F400= | Splice Region (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- HECTD3 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 173/340 reads (51%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, varscan2
- IRX1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 438/692 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- MINAR1 | c.1047A>T p.Q349H | Missense Mutation (SNP) | VAF 222/336 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, varscan2
- MXRA5 | c.4427C>A p.T1476N | Missense Mutation (SNP) | VAF 147/305 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); called by mutect2, varscan2
- PCDH10 | c.2683G>T p.V895F | Missense Mutation (SNP) | VAF 143/241 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PRG4 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 16/336 reads (5%) | called by muse, mutect2
- SESN1 | c.910G>A p.E304K (on ENST00000356644 / NM_001199933.1; = p.E363K on NM_014454.3) | Missense Mutation (SNP) | VAF 13/347 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC35B1 | c.707C>T p.T236I (on ENST00000649906; = p.T199I on NM_005827.4) | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SOX3 | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 386/890 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, varscan2
- SPOCD1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 136/292 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, varscan2
- TRIM63 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 133/269 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USH2A | c.10037C>A p.A3346E | Missense Mutation (SNP) | VAF 358/479 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, varscan2
- AC011448.1 | c.555C>T p.N185= | Silent (SNP) | VAF 270/448 reads (60%) | catalogued as rs369545105; called by muse, varscan2
- ADAMTS10 | c.372C>T p.Y124= | Silent (SNP) | VAF 154/494 reads (31%) | catalogued as rs138572540; called by muse, varscan2
- ADCY8 | c.75C>T p.G25= | Silent (SNP) | VAF 234/713 reads (33%) | called by muse, varscan2
- ARRB1 | c.1026C>T p.D342= | Silent (SNP) | VAF 226/340 reads (66%) | catalogued as rs150290364; called by muse, varscan2
- CACHD1 | c.2739G>A p.T913= | Silent (SNP) | VAF 74/158 reads (47%) | catalogued as rs1202602620, COSV51553609; called by muse, varscan2
- CADPS | c.2148C>T p.C716= | Silent (SNP) | VAF 90/302 reads (30%) | catalogued as rs368353277; called by muse, mutect2, varscan2
- CDC6 | c.1056C>T p.V352= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as rs1245468013; called by muse, mutect2
- CDKL5 | c.2670G>T p.R890= | Silent (SNP) | VAF 142/307 reads (46%) | called by muse, varscan2
- DAAM1 | c.1386A>G p.L462= | Silent (SNP) | VAF 71/268 reads (26%) | catalogued as rs1214958284, COSV100658423; called by muse, mutect2, varscan2
- DCLK1 | c.213G>T p.G71= | Silent (SNP) | VAF 120/501 reads (24%) | called by mutect2, varscan2
- FAM126A | c.1335C>T p.T445= | Silent (SNP) | VAF 180/454 reads (40%) | catalogued as rs776382371; called by muse, mutect2, varscan2
- FAM189A2 | c.1263G>A p.A421= | Silent (SNP) | VAF 160/653 reads (25%) | catalogued as rs772335309; called by muse, varscan2
- FRMD6 | c.1635C>T p.L545= (on ENST00000344768 / NM_001267046.2; = p.L537= on NM_152330.4) | Silent (SNP) | VAF 246/475 reads (52%) | catalogued as rs1179548355, COSV100656348; called by muse, mutect2, varscan2
- FZD10 | c.1179G>A p.A393= | Silent (SNP) | VAF 128/448 reads (29%) | catalogued as rs543088043; called by muse, varscan2
- MKNK2 | c.93C>T p.P31= | Silent (SNP) | VAF 166/454 reads (37%) | catalogued as rs919109829; called by muse, varscan2
- MTOR | c.1023C>T p.G341= | Silent (SNP) | VAF 141/311 reads (45%) | called by muse, varscan2
- NFATC2 | c.2199G>A p.T733= | Silent (SNP) | VAF 591/875 reads (68%) | catalogued as rs558006319, COSV65354617; called by muse, mutect2, varscan2
- NINL | c.2313C>T p.R771= | Silent (SNP) | VAF 671/1009 reads (67%) | catalogued as rs1292476724; called by muse, mutect2, varscan2
- OGDHL | c.69C>T p.D23= | Silent (SNP) | VAF 189/498 reads (38%) | catalogued as rs761258380, COSV65103528; called by muse, varscan2
- OR51A4 | c.264G>C p.L88= | Silent (SNP) | VAF 100/350 reads (29%) | catalogued as COSV66749337; called by muse, varscan2
- OR8H2 | c.72C>A p.I24= | Silent (SNP) | VAF 150/251 reads (60%) | catalogued as COSV57943031; called by muse, varscan2
- PDZK1IP1 | c.201C>T p.T67= | Silent (SNP) | VAF 83/195 reads (43%) | catalogued as rs138001097; called by muse, varscan2
- PGAP4 | c.549G>A p.S183= | Silent (SNP) | VAF 242/459 reads (53%) | catalogued as rs535197432, COSV66388136; called by muse, varscan2
- PPP2R2A | c.627C>T p.D209= | Silent (SNP) | VAF 61/122 reads (50%) | called by muse, mutect2, varscan2
- PRSS35 | c.1029G>A p.S343= | Silent (SNP) | VAF 151/425 reads (36%) | catalogued as rs757228644, COSV63800234; called by muse, varscan2
- PZP | c.297G>T p.V99= | Silent (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- RSPH6A | c.147C>T p.D49= | Silent (SNP) | VAF 310/476 reads (65%) | catalogued as rs1207903523; called by muse, varscan2
- SCTR | c.588C>T p.D196= | Silent (SNP) | VAF 231/441 reads (52%) | catalogued as rs746911205, COSV50026827; called by muse, mutect2, varscan2
- SEC22C | c.594T>C p.C198= | Silent (SNP) | VAF 113/386 reads (29%) | called by muse, mutect2, varscan2
- SLC1A2 | c.624C>T p.T208= | Silent (SNP) | VAF 100/359 reads (28%) | called by muse, mutect2, varscan2
- SLC9B2 | c.1288T>C p.L430= | Silent (SNP) | VAF 186/287 reads (65%) | called by muse, mutect2, varscan2
- TMEM132D | c.1878C>T p.G626= | Silent (SNP) | VAF 82/295 reads (28%) | catalogued as rs140308183; called by muse, varscan2
- TTN | c.71559C>T p.D23853= (on ENST00000591111; = p.D16429= on NM_003319.4) | Silent (SNP) | VAF 232/457 reads (51%) | catalogued as rs370908118; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- TTN | c.53181C>A p.G17727= (on ENST00000591111; = p.G10303= on NM_003319.4) | Silent (SNP) | VAF 152/336 reads (45%) | called by mutect2, varscan2
- VIPAS39 | c.78C>T p.D26= | Silent (SNP) | VAF 171/256 reads (67%) | catalogued as rs112217896; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- ARHGEF4 | chr2:130915738 G>A | 5'Flank (SNP) | VAF 302/643 reads (47%) | catalogued as rs1025906166; called by muse, varscan2
- CAPZB | c.*18C>T | 3'UTR (SNP) | VAF 109/237 reads (46%) | called by muse, varscan2
- MYOSLID | n.158G>A | RNA (SNP) | VAF 282/536 reads (53%) | catalogued as rs144141552; called by muse, mutect2, varscan2
